Surgical pathology report (de-identified scan), TCGA case TCGA-A2-A04X, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Walter Reed, specimen TCGA-A2-A04X-01A (Primary Tumor).

[page 1 of 3]
100-0-3

Carcinoma, infiltrating ductal, NOS 8500/3

Site: breast, NOS C50.9 1/24/11 JW

FOR OFFICIAL USE ONLY - PERSONAL DATA - PRIVACY ACT OF 1974

SURGICAL PATHOLOGY REPORT

Patient: Specimen #:
FMP/SSN:
DOB/Age/Sex: Race: WHITE Taken:
Location: Received:
Physician(s): Reported:

SPECIMEN:

A: LEFT BREAST B: SENTINEL LYMPH NODE #1
C: SENTINEL LYMPH NODE #2 AND #3 D: RIGHT BREAST

FINAL DIAGNOSIS:

- A. BREAST, LEFT, MASTECTOMY:
-INFILTRATING DUCTAL CARCINOMA, MODERATELY-DIFFERENTIATED.
-NOTTINGHAM SCORE IS 7 (3 TUBULES, 2 NUCLEI, 2 MITOSIS).
-TUMOR SIZE 3.5 CM (GROSS MEASUREMENT).
-DCIS PRESENT, CRIBRIFORM, NUCLEAR GRADE II WITH NECROSIS.
-NO LYMPHOVASCULAR INVASION PRESENT.
-SKIN AND NIPPLE ARE NOT INVOLVED.
-MARGINS ARE NEGATIVE.
- B. SENTINEL LYMPH NODE, EXCISION:
-ONE LYMPH NODE NEGATIVE BY H&E AND IMMUNOHISTOCHEMICAL STAINS.
- C. SENTINEL LYMPH NODE #2 AND #3, EXCISION:
-TWO LYMPH NODES NEGATIVE FOR MALIGNANCY BY H&E AND IMMUNOHISTOCHEMICAL STAINS.
- D. RIGHT BREAST, MASTECTOMY:
-MILD FIBROCYSTIC CHANGES CONSISTING OF APOCRINE METAPLASIA, FOCAL DUCTAL DILATATION AND MILD FIBROSIS.

AJCC STAGING:p T2 N0 MX

** Report Electronically Signed Out **

CLINICAL DIAGNOSIS AND HISTORY:

-year-old female with breast carcinoma.

Page 1

Continued on Next Page

- PERSONAL DATA - PRIVACY ACT OF 1974

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

Patient:

Specimen #:

GROSS DESCRIPTION:

A. Received fresh, labeled with the patient's name, designated "LEFT BREAST, LONG LATERAL, SHORT SUPERIOR" is a left mastectomy specimen. The specimen consists of a 921 gram left mastectomy specimen received fresh and oriented with a short suture superior and long stitch lateral. The specimen measures 23.0 cm from superior to inferior, 21.0 cm from medial to lateral, and 4.0 cm anterior to posterior. The 9.0 x 5.0 cm superficial skin ellipse is essentially located, 0.8 cm near the nipple free of discharge. No scars are noted. The superficial surface is partially inked blue, the deep margin is inked black. Serial sections reveal a 3.5 x 2.5 x 2.2 cm firm, pink-tan, fairly well circumscribed mass in the mid outer breast. The mass is located 3.5 cm from the deep margin, and 0.8 cm from the superficial inked surface. Located 2.0 cm medial to this mass (also at the mid outer breast) is a 1.0 x 1.0 x 0.5 cm irregular nodularity, which, upon resection, appears to consist of a cystic fibrous tissue. The cystic tissue is located 2.0 cm from the deep margin. The remainder of the specimen is composed of lobulated adipose tissue admixed with 50% focally cystic fibrous tissue, with this area located in the lower quadrant. No additional lesions are identified. No lymph nodes are identified. Representative sections are submitted as follows:

Cassette Key:

- A1: Skin.
- A2: Mass.
- A3: Mass with superficial margin.
- A4: Mid outer cystic tissue.
- A5: Upper outer quadrant.
- A6: Upper inner quadrant.
- A7: Lower inner quadrant with margin 1.5 cm away.
- A8: Lower outer quadrant. Matched sections of A1, A2, A4-A8 are submitted in OCT for CBCP protocol. Additional sections are submitted as follows:
- A9: Nipple.
- A10-A11: Additional sections of mass.
- A12-A13: Sections of the possible smaller mass and outer quadrant.
- 13CFSS.

B. Received fresh, labeled with the patient's name, designated "SENTINEL LYMPH NODE #1" is a firm, tan fragment of soft tissue measuring 0.7 x 0.6 x 0.3 cm. The specimen is bisected, and submitted entirely. Cut section reveals a variegated, tan, soft tissue.

C. Received fresh, labeled with the patient's name, designated "SENTINEL LYMPH NODE #2 AND #3" are two intact pink-tan lymph

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

Patient:

Specimen #:

GROSS DESCRIPTION (continued):

nodes with attached fatty tissue measuring 1.5 x 1.0 x 0.1 cm, and 1.0 x 0.7 x 0.4 cm. These lymph nodes are submitted as follows:

Cassette Key:

C1: One lymph node bisected.
C2: Largest lymph node. A matched section of lymph node is submitted in OCT for CBCP protocol. There is also an additional portion of yellow, adipose tissue that is submitted separately measuring 1.5 x 1.0 x 0.2 cm. This is submitted in cassette C3. 3CF

D. Received fresh, labeled with the patient's name, designated "RIGHT BREAST, LONG LATERAL, SHORT SUPERIOR" is a right mastectomy specimen. Received fresh is a 609 gram right mastectomy specimen oriented with a short suture superior, and long stitch lateral. The specimen measures 19.0 cm superior to inferior, 18.0 cm medial to lateral, and 3.0 cm anterior to posterior. The superficial skin ellipse measures 10.0 x 4.5 cm and displays a 1.0 cm centrally located, nipple free of discharge. No scars are identified. The deep margins are inked black. Serial sections reveal densely fibrous breast tissue admixed with approximately 10% adipose tissue. No discrete masses or lymph nodes are identified. Representative sections are submitted as follows:

Cassette Key:

D1: Skin.
D2: Upper outer quadrant.
D3: Lower outer quadrant.
D4: Left inner quadrant.
D5: Upper inner quadrant. Matched sections of D1 and D5 are submitted in OCT for CBCP protocol. Additional sections are submitted as follows:

D6: Nipple.
D7: Upper outer quadrant.
D8: Lower outer quadrant.
D9: Upper inner quadrant.
D10: Lower inner quadrant. 10CF

IHPAA Discrepancy		

Source: NCI Genomic Data Commons file 1fef7be0-0d6d-415e-88b5-3b9fc07dc492 (TCGA-A2-A04X.F114D078-5F03-47F8-82AE-B8A21C2F9D31.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).